Gene-level copy-number profile of tumor specimen ALCH-ABW4-TTP1-A from ALCHEMIST case ALCH-ABW4, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 64.9 years (23,716 days).
Specimen ALCH-ABW4-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 179b3555-6c0e-44e3-8b2e-84838d74f405.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-ABW4-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,232 have no estimate.
https://portal.gdc.cancer.gov/files/70527828-ec56-4325-8172-deb64b4daf40

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 335; copy number 1: 4,981; copy number 2: 51,848; copy number 3: 1,137; copy number 4: 53; copy number 5: 22; copy number 6: 6; copy number 7: 6; copy number 8: 2; copy number 9: 1.

Homozygous deletions (total copy number 0; autosomes only): 319 genes in 64 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:21,822,244–21,937,310, 2 genes (within-gene range 0–2): HSPG2, AL590556.1.
- chr1:22,710,839–22,921,500, 4 genes (within-gene range 0–1): EPHB2, MIR4684, AL512444.1, MIR4253.
- chr1:143,498,785–143,729,570, 9 genes: AC239859.2, LINC02799, AC239859.1, NBPF17P, PFN1P12, RNU1-114P, RNVU1-17, RNVU1-23, RNVU1-18.
- chr2:15,903,669–16,087,201, 7 genes (within-gene range 0–1): AC010145.2, MYCNOS, MYCNUT, MYCN, RN7SL104P, AC010145.1, GACAT3.
- chr2:89,170,775–89,177,160, 3 genes (within-gene range 0–2): IGKV1-22, IGKV2-23, IGKV2-24.
- chr3:184,505,113–184,556,918, 2 genes (within-gene range 0–2): LINC01839, LINC01840.
- chr4:49,203,171–49,246,915, 7 genes: AC118282.3, AC118282.2, AC118282.4, SNX18P23, AC118282.1, MTCO3P39, MTND3P22.
- chr4:49,502,145–51,919,381, 14 genes: ANKRD20A17P, AC119751.5, AC119751.2, AC119751.8, AC119751.7, MTCO3P42, AC119751.1, AC119751.6, SNX18P24, AC119751.4, SNX18P25, DCUN1D4, DUTP7, AC027271.1.
- chr4:77,157,207–77,433,388, 4 genes (within-gene range 0–2): CCNG2, AC008638.3, AC008638.2, AC008638.1.
- chr6:37,543,553–37,571,460, 4 genes: AL353597.2, AL353597.1, MIR4462, AL353597.3.
- chr7:62,275,361–63,088,261, 5 genes: AC128676.1, RNU6-417P, AC069285.2, AC069285.3, ZNF90P3.
- chr8:43,672,823–46,028,892, 3 genes: AC139365.2, AC139365.1, AC118650.1.
- chr9:61,190,003–61,453,030, 7 genes: SPATA31A7, BX005040.3, BX005040.2, FAM74A4, BX005040.1, CNTNAP3C, RN7SL462P.
- chr9:61,615,835–61,666,386, 4 genes: FAM242D, Y_RNA, AL935212.1, AL935212.2.
- chr10:38,601,418–42,281,819, 13 genes: ABCD1P2, AL133173.2, PABPC1P12, SLC9B1P3, ACTR3BP5, CHEK2P5, AL133173.1, AL590623.1, KSR1P1, IGKV1OR10-1, AL031601.1, AL031601.2, PABPC1P8.
- chr10:114,239,254–114,294,489, 3 genes: VWA2, AURKAP2, AC005383.1.
- chr11:48,880,111–48,908,946, 4 genes: AC027369.6, AC027369.3, AC027369.4, AC027369.5.
- chr11:50,279,828–54,725,816, 16 genes: AC109635.2, AC109635.1, LINC02750, AC024405.2, AC024405.1, OR4C50P, OR4C46, OR4C7P, OR4R2P, OR4A4P, OR4A3P, OR4A2P, OR4A8, OR4A7P, OR4A5, OR4A6P.
- chr11:70,467,856–71,568,934, 22 genes (within-gene range 0–2): SHANK2, AP001271.1, AP001271.2, SHANK2-AS1, SHANK2-AS2, Y_RNA, AP000590.1, SHANK2-AS3, MIR3664, AP003783.1, ACTE1P, DHCR7, AP002387.1, NADSYN1, MIR6754, AP000867.2, KRTAP5-7, KRTAP5-8, KRTAP5-9, AP000867.5, KRTAP5-10, AP000867.1.
- chr11:119,608,423–119,729,200, 4 genes: AP003393.1, NECTIN1, RNU6-1123P, NECTIN1-AS1.
- chr12:3,171,657–3,211,917, 2 genes (within-gene range 0–1): AC005912.2, AC005912.1.
- chr12:37,575,587–38,167,631, 7 genes: ZNF970P, AK6P2, CLUHP8, AC079460.1, AC079460.2, RNA5SP358, RNA5SP359.
- chr12:111,304,142–111,403,310, 5 genes (within-gene range 0–2): MIR6760, RNA5SP373, PHETA1, LINC02356, HSPA8P14.
- chr14:18,333,726–19,131,167, 34 genes (within-gene range 0–2): CR383658.1, RNU6-458P, CR383658.2, BNIP3P6, CR383656.10, CR383656.7, CR383656.13, CR383656.9, OR11H12, CR383656.6, ARHGAP42P5, LINC02297, CR383656.5, CR383656.1, CR383656.12, CR383656.8, CR383656.11, CR383656.3, RPL22P20, CR383656.4, CR383656.2, NF1P10, NEK2P1, NF1P7, MED15P1, AL929601.1, AL929601.2, POTEM, AL929601.3, RNU6-1239P, AL589182.1, GRAMD4P4, DUXAP9, AL589182.3.
- chr15:64,739,891–64,775,589, 2 genes: RBPMS2, MIR1272.
- chr15:65,895,079–66,253,747, 2 genes: MEGF11, MIR4311.
- chr16:81,100,875–81,220,370, 3 genes: PKD1L2, RNU6-1191P, AC092718.9.
- chr16:90,019,629–90,044,975, 2 genes (within-gene range 0–1): GAS8, GAS8-AS1.
- chr17:36,861,674–36,944,612, 3 genes: LHX1-DT, LHX1, AC243773.1.
- chr17:45,894,551–46,028,334, 5 genes (within-gene range 0–2): MAPT, MAPT-IT1, CR936218.2, Metazoa_SRP, STH.
- chr17:61,354,763–61,413,280, 6 genes (within-gene range 0–2): AC005746.3, AC005746.2, AC005746.1, TBX2-AS1, TBX2, LINC02875.
- chr17:66,964,707–67,056,797, 4 genes: CACNG4, AC005544.1, AC005544.2, CACNG1.
- chr17:72,627,231–72,644,490, 2 genes (within-gene range 0–1): RPL32P33, AC080037.2.
- chr18:37,243,040–37,762,131, 6 genes (within-gene range 0–1): CELF4, AC015961.2, AC090386.1, AC090386.2, AC129908.1, AC009899.1.
- chr19:24,146,701–24,163,425, 2 genes: AC073534.2, AC073534.1.
- chr19:38,211,006–38,304,910, 6 genes: DPF1, SPINT2, PPP1R14A, AC011479.1, AC011479.4, Y_RNA.
- chr21:7,744,962–9,129,752, 42 genes: SMIM11B, FAM243B, SMIM34B, KCNE1B, CU633980.1, FP671120.5, FP671120.4, MIR6724-1, FP671120.1, MIR3648-1, FP671120.2, FP671120.6, RNA5-8SN2, MIR6724-2, FP671120.3, FP671120.7, 5_8S_rRNA, FP236383.3, MIR6724-3, FP236383.1, FP236383.4, RNA5-8SN3, MIR6724-4, FP236383.2, FP236383.5, RNA5-8SN1, RPSAP68, CR381572.2, CR381572.1, LINC01666, CR381670.2, SNX18P10, MTCO1P1, CR381670.1, MIR3648-2, CR392039.1, CR392039.3, CDRT15P9, CR392039.4, TEKT4P2, SOWAHCP2, CR392039.2.
- chr21:10,649,400–13,120,807, 6 genes: IGHV1OR21-1, AP001464.1, ANKRD30BP2, RNU6-614P, ZNF355P, AJ239321.1.
- chr22:17,787,649–18,205,915, 17 genes (within-gene range 0–1): MICAL3, AC016026.1, AC016026.2, MIR648, AC016027.3, AC016027.2, RHEBP3, LINC01634, AC016027.1, PEX26, AC016027.5, AC016027.4, ARL2BPP10, TUBA8, AC008079.1, USP18, FAM230D.
- chr22:35,526,932–35,553,999, 2 genes: AL022334.2, RASD2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 37 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:12,938,472–13,032,130, 2 genes, copy number 8 (within-gene range 1–8): PRAMEF6, PRAMEF28P.
- chr1:28,887,091–29,120,046, 4 genes, copy number 5 (within-gene range 2–5): EPB41, AL138785.1, Y_RNA, Metazoa_SRP.
- chr5:135,802,985–135,803,075, 1 gene, copy number 9: MIR5692C1.
- chr16:88,638,572–88,651,054, 2 genes, copy number 5: IL17C, CYBA.
- chr16:88,803,789–88,811,937, 2 genes, copy number 7: CDT1, APRT.
- chr17:16,786,489–16,804,455, 1 gene, copy number 5 (within-gene range 2–5): USP32P1.
- chr17:16,788,879–16,805,707, 2 genes, copy number 5 (within-gene range 2–5): FAM106C, AC022596.1.
- chr17:48,133,442–48,430,275, 1 gene, copy number 5 (within-gene range 2–7): SKAP1.
- chr17:48,294,335–48,382,586, 3 genes, copy number 5–7: THRA1/BTR, AC036222.2, U3.
- chr20:62,796,473–62,969,585, 11 genes, copy number 5–7: MRGBP, OGFR-AS1, OGFR, COL9A3, TCFL5, DPH3P1, ARF4P2, DIDO1, AL117379.1, GID8, SLC17A9.
- chr20:63,627,227–63,657,682, 2 genes, copy number 5: MHENCR, STMN3.
- chr22:50,523,568–50,543,011, 6 genes, copy number 6: SCO2, U62317.1, TYMP, ODF3B, U62317.3, KLHDC7B-DT.

Autosomal genes at a single copy (total copy number 1): 4,974. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
